Gene-level copy-number profile of tumor specimen MP2PRT-PAVSAG-TMP1-A from MP2PRT case MP2PRT-PAVSAG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (988 days).
Specimen MP2PRT-PAVSAG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 88e42087-2a90-404c-88ff-a905ef40bb44.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVSAG-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/d7817a59-860c-4f5d-ad38-85c1ac86d8a9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 101; copy number 2: 41,094; copy number 3: 16,456; copy number 4: 730.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:62,444,256–62,569,907, 6 genes: BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
